Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5463, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5463-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Report Status: Amend/Addenda

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "LEFT KIDNEY":

RENAL CELL CARCINOMA (12.8 cm), Clear cell type,
Fuhrman nuclear grade II/IV.

The tumor abuts but does not invade the renal capsule.

The tumor invades the renal sinus and abuts the endothelium
of large veins (tumor is not present in the renal vein).

The tumor shows extensive hyalinization.

The ureter, renal artery, and renal vein resection margins are
negative for tumor.

AJCC Classification: T3a Nx MX.

The non-neoplastic kidney will be evaluated by the Renal Pathology
Division, and the findings will be reported in an addendum.

CLINICAL DATA:

History: None given.

Operation: Left radical nephrectomy.

Operative Findings: None given.

Clinical Diagnosis: Left renal mass.

ORGANS/TISSUE SUBMITTED:

A/1. Left kidney.

GROSS DESCRIPTION:

The specimen is received fresh, in one part, labeled with the patient's name, medical record number and "Left kidney", and consists of a 1642-gram nephrectomy specimen (24.5 x 13.0 x 9.8 cm) with ureter (11.5 in length x 0.4 cm in diameter), renal vein (1.3 cm in length x 0.5 cm in diameter), and renal artery (2.3 cm in length x 0.5 cm in diameter). No adrenal glands are identified. There is a tan/red to tan/yellow, loculated, partially encapsulated mass (12.8 x 10.3 x 8.5 cm) in the lower pole, replacing the majority of the lower pole parenchyma. It is less than 0.1 cm to the black inked resection margin, 6.0 cm to the ureteral margin, 2.0 cm to the renal vein margin, and 2.2 cm to the renal artery resection margin. The tumor extends to the surface of the adhered ureter. Representative sections of the tumor are submitted for cytogenetics, EM, quick fix, and tissue bank. Representative sections of the normal renal parenchyma are submitted for tissue banking, IF, and EM. Gross photographs are taken.

Micro A1: Resection margin for the renal vein, the renal artery, and the ureter, 3 frags, [REDACTED]

Micro A2-A4: Representative sections of the tumor, 3 frags in A2, 1 frag in A3 and 2 frags in A4, 6 frags total, [REDACTED]

Micro A5: The tumor in relation to the closest resection margin, which was inked black, 1 frag, [REDACTED]

Micro A6-A7: Tumor in relation to the adhered ureter, 2 frags, 1 frag in each block, [REDACTED]

Micro A8: The tumor in relation to the renal pelvis, 1 frag, [REDACTED]

Micro A9: The tumor in relation to perirenal adipose tissue, 1 frag, [REDACTED]

Micro A10: The tumor in relation to surrounding normal renal parenchyma, 1 frag, [REDACTED]

Micro A11: The normal renal parenchyma, 1 frag, [REDACTED]

[page 2 of 3]
TCGA-CZ-5463

[page 3 of 3]
Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

PATIENT

Cytogeneticist: [REDACTED]

KARYOTYPE: T1:42,X,-Y,-3,-8,-14[5] T3 :42,-Y,-3,-8,-14[5]

METAPHASES COUNTED: 10 ANALYZED: 10 SCORED: 0 BANDING: GTG

INTERPRETATION:

Three different specimens from this tumor were received.

All metaphases from specimens labeled T1 and T3 contained clonal aberrations including monosomy for chromosome 3, which is a typical finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

No metaphases were available from specimen T2, therefore the cytogenetic analysis could not be performed.

INDICATION FOR TEST:

? RCC; Kidney Tumor #1-#3

[REDACTED]

Source: NCI Genomic Data Commons file bd1144c8-1ff8-4498-8ea1-013837dfc27a (TCGA-CZ-5463.324D4D25-E72E-4FAA-BD17-6C2201A2D6CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).